Somatic mutation profile of tumor specimen TCGA-33-4583-01A (aliquot TCGA-33-4583-01A-01D-1441-08) from TCGA case TCGA-33-4583, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 73.4 years (26,799 days).
Specimen TCGA-33-4583-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de21aeab-a63d-46b1-9dd3-610b006d24d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-33-4583-11A (Solid Tissue Normal), aliquot TCGA-33-4583-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/426d3899-7909-4b69-83f4-c76bf5faf575

The open-access MAF lists 632 somatic variants for this specimen: 466 protein-altering or splice-affecting, 144 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 392, Silent 144, Nonsense Mutation 37, Frame Shift Del 17, Intron 11, Splice Site 11, Frame Shift Ins 5, RNA 5, 5'Flank 3, 3'UTR 2, Splice Region 2, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.1038C>G p.Y346* | Nonsense Mutation (SNP) | VAF 33/48 reads (69%) | hotspot (GDC flag); catalogued as COSV64288748, COSV64295099; called by muse, mutect2, varscan2
- TP53 | c.745A>T p.R249W | Missense Mutation (SNP) | VAF 17/92 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 28/85 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55113735; called by muse, mutect2, varscan2
- ABCA8 | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV52196239; called by muse, mutect2, varscan2
- ABCC10 | c.3546G>T p.G1182= (on ENST00000372530 / NM_001198934.2; = p.G1154= on NM_033450.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 48/236 reads (20%) | catalogued as rs780399103, COSV55085346; called by muse, varscan2
- ACAD10 | c.1821G>C p.E607D | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV58154689; called by muse, mutect2, varscan2
- ACSBG1 | c.1730A>G p.N577S | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV51903890; called by muse, mutect2, varscan2
- ACSS1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV60218284; called by muse, mutect2, varscan2
- ADAM20 | c.1495G>T p.V499L | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV56454285; called by muse, mutect2, varscan2
- ADAMTS12 | c.2134G>C p.E712Q | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV61257354; called by muse, mutect2, varscan2
- ADAMTS12 | c.1760G>T p.R587L | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV61257360, COSV61262119; called by muse, mutect2, varscan2
- ADAMTS20 | c.4309A>G p.R1437G | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV67128513; called by muse, mutect2
- ADAMTS20 | c.3032G>T p.R1011L | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs137911452, COSV67128520; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1093G>T p.E365* | Nonsense Mutation (SNP) | VAF 66/204 reads (32%) | catalogued as COSV54439246; called by muse, mutect2, varscan2
- ADCY8 | c.2418G>A p.W806* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV53899144; called by muse, mutect2, varscan2
- ADGRG4 | c.3530T>C p.V1177A | Missense Mutation (SNP) | VAF 104/141 reads (74%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as rs761516509, COSV54951283; called by muse, mutect2, varscan2
- ADGRV1 | c.14486A>G p.Y4829C | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV67979973; called by muse, mutect2, varscan2
- ADRA2B | c.475C>T p.R159C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs776748854, COSV69787252; called by muse, mutect2, varscan2
- AHDC1 | c.4225A>C p.K1409Q | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.719); catalogued as COSV55937220; called by muse, mutect2, varscan2
- AK9 | c.2765T>C p.M922T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV58138959; called by muse, mutect2, varscan2
- AKAP3 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.464); catalogued as COSV57414634; called by muse, mutect2, varscan2
- AKAP7 | c.161A>T p.E54V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV63504854; called by muse, mutect2, varscan2
- AMACR | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV59460086; called by muse, mutect2, varscan2
- AMZ2 | c.751-1G>T p.X251_splice | Splice Site (SNP) | VAF 63/162 reads (39%) | catalogued as COSV100703076, COSV63082584; called by muse, mutect2, varscan2
- ANAPC1 | c.1805G>A p.G602D | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.59); catalogued as COSV61974629; called by muse, mutect2, varscan2
- ANAPC5 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as rs782122962, COSV55841738; called by muse, mutect2, varscan2
- ANKS3 | c.955A>G p.T319A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); catalogued as COSV58507707; called by muse, mutect2, varscan2
- ARHGAP45 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.652); catalogued as rs918382275, COSV99565969; called by muse, mutect2, varscan2
- ARID4B | c.3893C>G p.S1298* | Nonsense Mutation (SNP) | VAF 57/128 reads (45%) | catalogued as COSV51599795; called by muse, mutect2, varscan2
- ARMC3 | c.1562+1G>T p.X521_splice | Splice Site (SNP) | VAF 33/57 reads (58%) | catalogued as COSV99958227; called by muse, mutect2, varscan2
- ARMH4 | c.2126G>T p.G709V | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs766680136, COSV50762259; called by muse, varscan2
- ASPM | c.7598C>T p.S2533F | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54126033, COSV54126089; called by muse, mutect2, varscan2
- ASPM | c.6376A>T p.M2126L | Missense Mutation (SNP) | VAF 71/366 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.028); catalogued as COSV54126040; called by muse, mutect2, varscan2
- ATAD2B | c.1850G>A p.C617Y | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53195939; called by muse, mutect2, varscan2
- ATF7IP | c.2878G>A p.G960S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.028); catalogued as COSV53767223, COSV53778249; called by muse, mutect2, varscan2
- ATP10A | c.4265G>T p.R1422M | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); catalogued as COSV63514597; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3852G>T p.K1284N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63244202; called by muse, mutect2, varscan2
- BPIFB4 | c.869T>A p.L290Q | Missense Mutation (SNP) | VAF 100/208 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV64950815; called by muse, varscan2
- BRCA2 | c.6947A>G p.K2316R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as rs1407242741, COSV66449704; called by muse, mutect2, varscan2
- BRCA2 | c.8465T>C p.I2822T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs1566248924, COSV66449723; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C1QTNF8 | c.229G>A p.V77I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.182); catalogued as rs759165911, COSV60518799; called by muse, varscan2
- C1orf43 | c.202A>T p.R68W (on ENST00000368521 / NM_001297718.2; = p.R34W on NM_015449.4) | Missense Mutation (SNP) | VAF 104/188 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV62965960; called by muse, varscan2
- C20orf194 | c.2149A>T p.I717F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV52692641; called by muse, mutect2, varscan2
- C2orf16 | c.1822C>A p.P608T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as COSV62674219; called by muse, mutect2, varscan2
- CACNA1E | c.6452C>A p.T2151N (on ENST00000367573 / NM_001205293.3; = p.T2108N on NM_000721.4) | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV62384891, COSV99052160; called by muse, varscan2
- CACNA1G | c.588C>A p.S196R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV61721345; called by muse, mutect2, varscan2
- CAD | c.4736A>T p.E1579V | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); catalogued as COSV53024350; called by muse, mutect2, varscan2
- CBFA2T2 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV61337928; called by muse, mutect2
- CCDC69 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 81/252 reads (32%) | catalogued as COSV62599187; called by muse, mutect2, varscan2
- CCDC85A | c.1324C>A p.Q442K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated, low confidence (0.31); PolyPhen possibly damaging (0.761); catalogued as COSV68148274; called by muse, mutect2, varscan2
- CD5 | c.1453A>G p.S485G | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57108104; called by muse, mutect2, varscan2
- CD80 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.137); catalogued as COSV51801621; called by muse, varscan2
- CDC27 | c.430T>G p.L144V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.574); catalogued as COSV50367517; called by muse, mutect2, varscan2
- CDCP2 | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61282841; called by muse, mutect2, varscan2
- CDH10 | c.1615G>T p.D539Y | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52573130, COSV52579326; called by muse, mutect2, varscan2
- CDH6 | c.1735A>T p.S579C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54065669; called by muse, mutect2, varscan2
- CELSR2 | c.2575G>C p.D859H | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201283895, COSV54768167; called by muse, mutect2, varscan2
- CENPF | c.5065G>T p.D1689Y | Missense Mutation (SNP) | VAF 44/167 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV65273196; called by muse, mutect2, varscan2
- CEP83 | c.924G>T p.L308F | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60406987; called by muse, mutect2, varscan2
- CETN1 | c.145G>T p.D49Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV59121022; called by muse, mutect2, varscan2
- CFAP43 | c.4534G>C p.E1512Q | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as COSV63852292; called by muse, mutect2, varscan2
- CFAP52 | c.69T>G p.N23K | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.147); catalogued as COSV60488330; called by muse, mutect2, varscan2
- CHI3L2 | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780579179, COSV63873506; called by muse, mutect2, varscan2
- CHST5 | c.673G>T p.D225Y | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60337524; called by muse, mutect2, varscan2
- CHSY3 | c.846G>T p.K282N | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV59273193; called by muse, mutect2, varscan2
- CLEC4E | c.303G>T p.W101C | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55225200; called by muse, mutect2, varscan2
- CLN5 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66283602; called by muse, mutect2, varscan2
- CLSTN2 | c.2117T>A p.L706* | Nonsense Mutation (SNP) | VAF 48/143 reads (34%) | catalogued as COSV71718865; called by muse, mutect2, varscan2
- CLTC | c.931G>T p.A311S | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT tolerated (0.91); PolyPhen benign (0.024); catalogued as COSV52245514, COSV52253641; called by muse, mutect2, varscan2
- COL11A1 | c.3178G>T p.G1060* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100617915, COSV62175404; called by muse, mutect2, varscan2
- COL19A1 | c.2461G>C p.E821Q | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV59567600; called by muse, mutect2, varscan2
- COL22A1 | c.4141-2A>T p.X1381_splice | Splice Site (SNP) | VAF 25/91 reads (27%) | catalogued as COSV57327416; called by muse, mutect2, varscan2
- COL27A1 | c.5135G>T p.G1712V | Missense Mutation (SNP) | VAF 123/217 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV61922629; called by muse, varscan2
- COL4A2 | c.958-1G>T p.X320_splice | Splice Site (SNP) | VAF 85/177 reads (48%) | catalogued as COSV64625747; called by muse, mutect2, varscan2
- CORO7 | c.898+2T>A p.X300_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV52028559; called by muse, mutect2, varscan2
- CPSF1 | c.1720T>A p.F574I | Missense Mutation (SNP) | VAF 12/311 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as COSV62939214; called by muse, mutect2
- CREB5 | c.37G>C p.E13Q (on ENST00000357727 / NM_182898.4; = p.E6Q on NM_004904.3) | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV63218187; called by muse, mutect2, varscan2
- CRISP3 | c.483G>T p.K161N (on ENST00000371159 / NM_001368123.1; = p.K143N on NM_006061.4) | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.295); catalogued as COSV53819429; called by muse, mutect2
- CRLF2 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 62/128 reads (48%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.577); catalogued as COSV101053723; called by muse, mutect2, varscan2
- CSMD3 | c.8060C>A p.P2687H (on ENST00000297405 / NM_001363185.1; = p.P2583H on NM_052900.3) | Missense Mutation (SNP) | VAF 57/209 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52122249; called by muse, mutect2, varscan2
- CSPP1 | c.1009G>T p.D337Y (on ENST00000676605; = p.D296Y on NM_024790.6) | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV51581139; called by muse, mutect2, varscan2
- CTNND2 | c.416C>A p.P139Q | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV58871225; called by muse, mutect2, varscan2
- CTTNBP2 | c.1174C>G p.P392A | Missense Mutation (SNP) | VAF 67/245 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV50391235; called by muse, mutect2, varscan2
- CWH43 | c.1659A>T p.E553D | Missense Mutation (SNP) | VAF 100/182 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as rs371357170; called by mutect2, varscan2
- CYP21A2 | c.715G>C p.E239Q | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.046); catalogued as COSV100926763, COSV64474914; called by muse, mutect2, varscan2
- DCAF5 | c.968A>G p.N323S | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as COSV58458963; called by muse, mutect2, varscan2
- DCDC1 | c.4264G>T p.G1422W (on ENST00000597505 / NM_001367979.1; = p.G529W on NM_020869.3) | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57997901; called by muse, mutect2, varscan2
- DCHS1 | c.4840G>T p.E1614* | Nonsense Mutation (SNP) | VAF 33/112 reads (29%) | catalogued as COSV55031863; called by muse, mutect2, varscan2
- DCP1B | c.1591G>T p.A531S | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV54967671; called by muse, mutect2, varscan2
- DEPDC4 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV100147349, COSV54553188, COSV54553229; called by muse, mutect2, varscan2
- DERA | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0.022); catalogued as COSV70773857; called by muse, mutect2, varscan2
- DLG2 | c.2461G>A p.D821N | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs868505277, COSV54627198; called by muse, mutect2, varscan2
- DLX3 | c.676C>A p.P226T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV71547539; called by muse, mutect2, varscan2
- DMXL2 | c.1273G>T p.D425Y | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV51842051; called by muse, mutect2, varscan2
- DMXL2 | c.1272T>G p.D424E | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV51842059; called by muse, mutect2, varscan2
- DNAAF3 | c.1474G>T p.G492C (on ENST00000524407 / NM_001256715.2; = p.G539C on NM_178837.4) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.717); catalogued as COSV61275525; called by muse, mutect2, varscan2
- DNAJB13 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as COSV60268756; called by muse, mutect2, varscan2
- DNMT1 | c.3386A>G p.E1129G | Missense Mutation (SNP) | VAF 81/235 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as COSV61577163; called by muse, mutect2, varscan2
- DOCK10 | c.5410T>C p.Y1804H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753949258, COSV51355570; called by mutect2, varscan2
- DOCK11 | c.773A>T p.Q258L | Missense Mutation (SNP) | VAF 95/142 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV52234953; called by muse, mutect2, varscan2
- DOCK8 | c.3118A>G p.K1040E | Missense Mutation (SNP) | VAF 91/124 reads (73%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV66618445; called by muse, mutect2, varscan2
- DOK3 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV57251266; called by muse, mutect2, varscan2
- DOK6 | c.109A>C p.K37Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV66927344; called by muse, mutect2
- DOK6 | c.111A>T p.K37N | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.765); catalogued as COSV66927359; called by muse, mutect2
- DPRX | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.089); catalogued as COSV64949277, COSV64949793; called by muse, mutect2, varscan2
- DRD2 | c.948C>A p.H316Q | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.215); catalogued as COSV60755246; called by muse, mutect2, varscan2
- DYNC1I1 | c.503A>G p.K168R | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100269724, COSV61457282; called by muse, mutect2, varscan2
- DYTN | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV71751699; called by muse, mutect2, varscan2
- EDRF1 | c.3211G>A p.D1071N (on ENST00000356792 / NM_001202438.2; = p.D1037N on NM_015608.2) | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61762687; called by muse, mutect2, varscan2
- ENOX1 | c.497G>A p.G166D | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54890288; called by muse, mutect2, varscan2
- EP400 | c.8434C>T p.Q2812* | Nonsense Mutation (SNP) | VAF 27/78 reads (35%) | catalogued as COSV57765230; called by muse, mutect2, varscan2
- EPPIN | c.262G>C p.A88P | Missense Mutation (SNP) | VAF 44/94 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.46); catalogued as COSV60548077; called by muse, mutect2, varscan2
- ETV1 | c.859A>T p.S287C | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV54138412; called by muse, mutect2, varscan2
- FAM135B | c.80A>G p.Y27C | Missense Mutation (SNP) | VAF 39/114 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50523153; called by muse, mutect2, varscan2
- FANCG | c.930G>C p.L310F | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62719854; called by muse, mutect2, varscan2
- FANCM | c.4864G>T p.E1622* | Nonsense Mutation (SNP) | VAF 41/103 reads (40%) | catalogued as COSV57498130; called by muse, mutect2, varscan2
- FBXL13 | c.1571G>A p.G524E | Missense Mutation (SNP) | VAF 55/145 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57535634; called by muse, mutect2, varscan2
- FBXO31 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61148001; called by muse, mutect2, varscan2
- FCGBP | c.4425C>G p.H1475Q | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV55430307; called by mutect2, varscan2
- FGG | c.553A>T p.K185* | Nonsense Mutation (SNP) | VAF 43/90 reads (48%) | catalogued as COSV60194720; called by muse, mutect2, varscan2
- FPR1 | c.956G>A p.S319N | Missense Mutation (SNP) | VAF 66/193 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV59051205; called by muse, mutect2, varscan2
- FSIP2 | c.19757T>A p.L6586* | Nonsense Mutation (SNP) | VAF 55/87 reads (63%) | catalogued as COSV100555375; called by muse, mutect2, varscan2
- GALNS | c.310G>T p.A104S | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); catalogued as COSV51936038; called by muse, mutect2
- GAS7 | c.941A>T p.D314V (on ENST00000432992 / NM_201433.2; = p.D174V on NM_003644.3) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV60432721; called by muse, mutect2, varscan2
- GFI1B | c.190C>A p.P64T | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59743909; called by muse, mutect2, varscan2
- GIMAP6 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV61032714; called by muse, mutect2, varscan2
- GLIPR1L2 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57553425; called by muse, mutect2, varscan2
- GML | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 31/140 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.856); catalogued as COSV55278002, COSV99638337; called by muse, mutect2, varscan2
- GNAT3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.804); catalogued as COSV68068057; called by muse, mutect2, varscan2
- GPC5 | c.249G>C p.Q83H | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.95); catalogued as COSV65581502, COSV65582941; called by muse, mutect2
- GPRASP1 | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 119/184 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.335); catalogued as COSV64354986; called by muse, mutect2, varscan2
- GRIN3A | c.506C>A p.P169H | Missense Mutation (SNP) | VAF 54/82 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV62451659; called by muse, mutect2, varscan2
- GRM6 | c.1940C>A p.A647D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV51435880; called by muse, mutect2, varscan2
- H2AC15 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 80/156 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV57584818; called by muse, mutect2, varscan2
- HBG2 | c.263A>G p.Q88R | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV57963134, COSV57963822; called by muse, varscan2
- HBG2 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100400646, COSV100400704; called by muse, varscan2
- HDC | c.377T>G p.M126R | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV51068602; called by muse, mutect2, varscan2
- HDHD5 | c.823G>T p.G275C (on ENST00000336737 / NM_033070.3; = p.G245C on NM_017829.5) | Missense Mutation (SNP) | VAF 133/303 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV50084631; called by muse, mutect2, varscan2
- HEATR5A | c.5126G>A p.G1709D | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV66338996; called by muse, mutect2, varscan2
- HEATR5B | c.4038G>T p.V1346= | Splice Region (SNP) | VAF 35/76 reads (46%) | catalogued as rs141463798, COSV51849955; called by muse, mutect2, varscan2
- HECW1 | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.593); catalogued as rs1301593547, COSV67820593, COSV67824248; called by muse, mutect2, varscan2
- HERC2 | c.11023G>C p.D3675H | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.964); catalogued as COSV55311846; called by muse, mutect2, varscan2
- HIVEP1 | c.4081C>T p.R1361W | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760191980, COSV65098767; called by muse, mutect2, varscan2
- HJV | c.629T>C p.L210S (on ENST00000336751 / NM_213653.4; = p.L97S on NM_145277.5) | Missense Mutation (SNP) | VAF 149/321 reads (46%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV60951424; called by muse, mutect2, varscan2
- ICE1 | c.3310G>T p.G1104* | Nonsense Mutation (SNP) | VAF 19/76 reads (25%) | catalogued as COSV56820524; called by muse, mutect2, varscan2
- IFI16 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 45/209 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV55531804, COSV55535449; called by muse, mutect2, varscan2
- IL1B | c.121C>A p.L41I | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.848); catalogued as COSV54521203, COSV54521314; called by muse, mutect2, varscan2
- IL1RAPL1 | c.332A>C p.Q111P | Missense Mutation (SNP) | VAF 31/59 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as COSV56243430; called by muse, mutect2, varscan2
- IL31RA | c.701G>T p.R234L | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as COSV51679762, COSV51679908; called by muse, mutect2, varscan2
- IQCF1 | c.15G>T p.Q5H | Missense Mutation (SNP) | VAF 159/295 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV58823149, COSV58823845; called by muse, mutect2, varscan2
- IRAK1 | c.1352G>T p.S451I | Missense Mutation (SNP) | VAF 92/142 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as COSV64110170; called by muse, mutect2, varscan2
- ISOC1 | c.716C>G p.S239* | Nonsense Mutation (SNP) | VAF 32/122 reads (26%) | catalogued as rs1452512315, COSV51491220; called by muse, mutect2, varscan2
- KBTBD3 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1452874825, COSV73241266, COSV73241408; called by muse, mutect2, varscan2
- KCNA6 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54974358; called by muse, mutect2, varscan2
- KCNC1 | c.636C>A p.H212Q | Missense Mutation (SNP) | VAF 49/158 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56392270, COSV56396398; called by muse, mutect2, varscan2
- KCNH1 | c.711T>A p.Y237* | Nonsense Mutation (SNP) | VAF 41/178 reads (23%) | catalogued as COSV55072386, COSV55094743; called by muse, mutect2, varscan2
- KCNH1 | c.235A>T p.T79S | Missense Mutation (SNP) | VAF 67/145 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as COSV55072394; called by muse, mutect2, varscan2
- KCNIP1 | c.343G>A p.G115S (on ENST00000411494 / NM_001034837.3; = p.G104S on NM_014592.4) | Missense Mutation (SNP) | VAF 49/155 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61081322; called by muse, mutect2, varscan2
- KIAA0408 | c.1439C>A p.T480N | Missense Mutation (SNP) | VAF 47/115 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV100846952; called by muse, mutect2, varscan2
- KLHDC7A | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1447482917, COSV68769175; called by muse, mutect2
- KLHL1 | c.1240C>A p.L414I | Missense Mutation (SNP) | VAF 43/127 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.206); catalogued as COSV64768135; called by muse, mutect2, varscan2
- KLHL1 | c.1239C>A p.D413E | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.348); catalogued as COSV64768140; called by muse, mutect2, varscan2
- KLHL1 | c.1000C>A p.H334N | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV100917430; called by muse, mutect2, varscan2
- KMT2B | c.6308C>T p.A2103V | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV55858230; called by mutect2, varscan2
- KRBA1 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV55440427; called by muse, mutect2, varscan2
- KRTAP13-2 | c.323G>C p.R108P | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.709); catalogued as COSV67761889, COSV67761896; called by muse, mutect2, varscan2
- KRTAP5-5 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated, low confidence (0.25); PolyPhen possibly damaging (0.907); catalogued as COSV68784440; called by muse, varscan2
- KYNU | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 47/146 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51580382; called by muse, mutect2, varscan2
- LAMB2 | c.3901G>T p.E1301* | Nonsense Mutation (SNP) | VAF 53/92 reads (58%) | catalogued as COSV59731488; called by muse, mutect2, varscan2
- LAMTOR2 | c.284C>A p.A95D | Missense Mutation (SNP) | VAF 102/202 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63107651; called by muse, mutect2, varscan2
- LILRB1 | c.1688C>A p.T563K (on ENST00000427581; = p.T513K on NM_006669.6) | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61116503; called by muse, varscan2
- LPL | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 53/174 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV60930390; called by muse, mutect2, varscan2
- LPO | c.1627C>G p.H543D | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.286); catalogued as COSV51857310; called by muse, mutect2, varscan2
- LRFN5 | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV53246426, COSV99982062, COSV99984147; called by muse, mutect2, varscan2
- LRP1B | c.10078G>T p.G3360C | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67195176; called by muse, mutect2, varscan2
- LRRK2 | c.4291A>G p.M1431V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV54146597; called by muse, mutect2, varscan2
- LRTM2 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV54564189; called by muse, mutect2, varscan2
- LYST | c.792A>C p.L264F | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67704180; called by muse, mutect2, varscan2
- MACROD2 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.819); catalogued as COSV53955119; called by muse, mutect2, varscan2
- MAGEC1 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 201/325 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.72); catalogued as COSV53569239; called by muse, mutect2, varscan2
- MAGEC3 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.265); catalogued as COSV53577104; called by muse, mutect2
- MAML2 | c.2729G>T p.R910L | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as COSV73262774, COSV73262922; called by muse, mutect2, varscan2
- MAN2A1 | c.854G>T p.G285V | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV54847164; called by muse, mutect2, varscan2
- MANEA | c.952G>T p.D318Y | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV62589329, COSV62590817; called by muse, mutect2, varscan2
- MAP4K1 | c.1313G>A p.R438H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs761081944, COSV67708983; called by muse, varscan2
- MARCHF6 | c.1432C>T p.R478* | Nonsense Mutation (SNP) | VAF 49/140 reads (35%) | catalogued as COSV56879467; called by muse, mutect2, varscan2
- MARK3 | c.307G>T p.E103* | Nonsense Mutation (SNP) | VAF 28/181 reads (15%) | catalogued as COSV53507368; called by muse, mutect2, varscan2
- MAST1 | c.1067A>T p.D356V | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV52242404; called by muse, mutect2, varscan2
- MED12L | c.4003A>G p.K1335E | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV56371412; called by muse, mutect2, varscan2
- MGAT2 | c.640G>T p.E214* | Nonsense Mutation (SNP) | VAF 64/155 reads (41%) | catalogued as COSV53565728; called by muse, mutect2, varscan2
- MNX1 | c.911A>G p.E304G | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV53317762; called by muse, mutect2, varscan2
- MON1B | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV50245573; called by muse, mutect2
- MORC1 | c.2510A>T p.Q837L | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51715740; called by muse, mutect2, varscan2
- MOSPD3 | c.460C>T p.P154S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.037); catalogued as rs780225536, COSV56157859, COSV56159077; called by muse, mutect2, varscan2
- MROH2B | c.3997G>C p.G1333R | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs377394471, COSV68181966; called by muse, mutect2, varscan2
- MRPL44 | c.146G>T p.R49L | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV51312330; called by muse, mutect2, varscan2
- MSLN | c.466G>T p.A156S | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV53499900, COSV53501793; called by muse, mutect2, varscan2
- MTMR10 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 47/148 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58727436; called by muse, mutect2, varscan2
- MTMR3 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60302243, COSV60308084, COSV60309028; called by muse, mutect2, varscan2
- MUC16 | c.31232C>G p.T10411R | Missense Mutation (SNP) | VAF 108/339 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV67451255; called by muse, mutect2, varscan2
- MUC16 | c.30837G>T p.M10279I | Missense Mutation (SNP) | VAF 50/132 reads (38%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); catalogued as COSV67451260; called by muse, mutect2, varscan2
- MUC5B | c.7033C>G p.R2345G | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101500412; called by muse, mutect2, varscan2
- MYBL1 | c.496A>G p.K166E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as COSV72918768; called by muse, mutect2, varscan2
- MYG1 | c.971G>T p.R324L | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV52932374; called by muse, mutect2, varscan2
- MYH4 | c.3047T>C p.M1016T | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs545765854, COSV55113838; called by muse, mutect2, varscan2
- MYH9 | c.1916G>A p.R639Q | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53382974; called by muse, mutect2, varscan2
- MYO18B | c.7667A>T p.D2556V | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV59127887; called by muse, mutect2, varscan2
- MYOCD | c.1945A>G p.I649V | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs775187138, COSV58498881; called by muse, mutect2, varscan2
- NCKAP1L | c.1211T>C p.I404T | Missense Mutation (SNP) | VAF 58/156 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs748982771, COSV53204257; called by muse, mutect2, varscan2
- NCOR2 | c.7105A>G p.N2369D | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as COSV62294519; called by muse, mutect2, varscan2
- NDEL1 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 21/90 reads (23%) | catalogued as COSV55325452; called by muse, mutect2, varscan2
- NDUFS8 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 32/360 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.457); catalogued as rs763234032, COSV50288019, COSV50288091; called by muse, mutect2
- NHSL2 | c.1237C>T p.P413S (on ENST00000510661; = p.P779S on NM_001013627.2) | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV65452595; called by muse, mutect2, varscan2
- NIN | c.421G>C p.G141R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.39); PolyPhen benign (0.238); catalogued as COSV55382537; called by muse, mutect2, varscan2
- NLRC5 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV99347502; called by mutect2, varscan2
- NLRP3 | c.674C>A p.A225E | Missense Mutation (SNP) | VAF 57/113 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as CM082975, COSV60221196; called by muse, mutect2, varscan2
- NLRP4 | c.1654G>C p.A552P | Missense Mutation (SNP) | VAF 37/114 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.852); catalogued as COSV56709508; called by muse, mutect2, varscan2
- NLRP5 | c.1053G>A p.M351I | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as rs760850161, COSV66762731; called by muse, mutect2, varscan2
- NOBOX | c.273del p.R93Gfs*81 | Frame Shift Del (DEL) | VAF 12/66 reads (18%) | catalogued as COSV56193864; called by mutect2, pindel, varscan2
- NOD1 | c.2741C>A p.A914D | Missense Mutation (SNP) | VAF 95/370 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV56111165; called by muse, mutect2, varscan2
- NOL4 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.349); catalogued as rs746220512, COSV52341252; called by muse, mutect2, varscan2
- NOSTRIN | c.674A>G p.N225S (on ENST00000317647 / NM_001039724.4; = p.N147S on NM_052946.3) | Missense Mutation (SNP) | VAF 81/138 reads (59%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV58319795; called by muse, mutect2, varscan2
- NOTCH1 | c.3643+1G>T p.X1215_splice | Splice Site (SNP) | VAF 55/90 reads (61%) | catalogued as COSV53034462, COSV99491080; called by muse, mutect2, varscan2
- NOTCH1 | c.3643G>T p.G1215C | Missense Mutation (SNP) | VAF 55/90 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53034480; called by muse, mutect2, varscan2
- NPC1L1 | c.1673G>T p.G558V | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56923097; called by muse, mutect2, varscan2
- NRG3 | c.1819G>T p.E607* (on ENST00000404547 / NM_001370084.1; = p.E583* on NM_001010848.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 135/231 reads (58%) | catalogued as COSV64548789; called by muse, mutect2, varscan2
- NRXN1 | c.148T>A p.C50S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV68005892; called by muse, mutect2, varscan2
- NTRK1 | c.1114G>T p.A372S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.44); PolyPhen benign (0.127); catalogued as rs754611476, COSV62324015, COSV62325910; called by muse, mutect2, varscan2
- NTRK1 | c.1502-1G>T p.X501_splice | Splice Site (SNP) | VAF 60/295 reads (20%) | catalogued as COSV62324030; called by muse, mutect2, varscan2
- NUF2 | c.197T>A p.M66K | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV54842513; called by muse, mutect2, varscan2
- NYAP1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55717635; called by muse, mutect2, varscan2
- OBSCN | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 34/60 reads (57%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.884); catalogued as rs1278352549, COSV52749325; called by muse, mutect2, varscan2
- OCA2 | c.1888T>G p.L630V | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV62340470; called by muse, mutect2, varscan2
- OCRL | c.1807C>T p.P603S | Missense Mutation (SNP) | VAF 75/117 reads (64%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63980342; called by muse, mutect2, varscan2
- OLFML2A | c.733G>C p.D245H | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV56582268; called by muse, mutect2
- OR10A3 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62459253, COSV62460367; called by muse, mutect2, varscan2
- OR10G8 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 96/268 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.049); catalogued as COSV70908235; called by muse, mutect2, varscan2
- OR10X1 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); catalogued as COSV63767064; called by muse, mutect2, varscan2
- OR1C1 | c.673G>C p.V225L | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs750404604, COSV68715498; called by muse, mutect2, varscan2
- OR2G6 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58573895; called by muse, mutect2, varscan2
- OR2T27 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV100788276; called by mutect2, varscan2
- OR2T4 | c.17G>A p.W6* | Nonsense Mutation (SNP) | VAF 36/140 reads (26%) | catalogued as COSV63543232; called by muse, mutect2, varscan2
- OR2Z1 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 51/150 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs998972147, COSV60691877; called by muse, varscan2
- OR4A15 | c.386A>G p.H129R | Missense Mutation (SNP) | VAF 20/368 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.071); catalogued as COSV59033936, COSV59033949; called by muse, mutect2
- OR4C13 | c.791C>A p.P264H | Missense Mutation (SNP) | VAF 79/268 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.25); catalogued as COSV73648663; called by muse, mutect2, varscan2
- OR4C15 | c.165G>T p.M55I (on ENST00000314644; = p.M1? on NM_001001920.2) | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV58951489, COSV58954298; called by muse, mutect2, varscan2
- OR4D2 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV73459715; called by muse, mutect2, varscan2
- OR4K1 | c.365G>C p.R122T | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53459128, COSV53461758, COSV53462479; called by muse, mutect2, varscan2
- OR4K14 | c.670C>A p.L224I | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as COSV59292313; called by muse, mutect2, varscan2
- OR4K15 | c.468C>A p.Y156* (on ENST00000305051; = p.Y132* on NM_001005486.1) | Nonsense Mutation (SNP) | VAF 67/191 reads (35%) | catalogued as COSV59300628; called by muse, mutect2, varscan2
- OR4X2 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 111/333 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs758213929, COSV100183236, COSV56582534; called by muse, mutect2, varscan2
- OR51F1 | c.469A>T p.M157L | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58579059; called by muse, mutect2, varscan2
- OR51V1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58314348; called by muse, mutect2, varscan2
- OR52L1 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV59986068; called by muse, mutect2, varscan2
- OR56A3 | c.679C>T p.R227* | Nonsense Mutation (SNP) | VAF 76/250 reads (30%) | catalogued as rs188845678, COSV61568609, COSV61569223; called by muse, varscan2
- OR6K3 | c.514C>G p.L172V (on ENST00000368146; = p.L156V on NM_001005327.2) | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.1); catalogued as COSV63745384; called by muse, mutect2, varscan2
- OR8A1 | c.363C>A p.D121E | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52508103; called by muse, mutect2, varscan2
- OR8D2 | c.175G>C p.V59L | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV62488188; called by muse, mutect2, varscan2
- OR8K5 | c.569C>G p.S190* | Nonsense Mutation (SNP) | VAF 54/138 reads (39%) | catalogued as COSV100537239, COSV57888096; called by muse, mutect2, varscan2
- PABPC4 | c.1420G>T p.D474Y | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV63293286; called by muse, varscan2
- PABPC4 | c.1418C>T p.P473L | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as COSV100790895, COSV63293292; called by muse, varscan2
- PARD3B | c.1438G>A p.G480R | Missense Mutation (SNP) | VAF 144/261 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62505110; called by muse, mutect2, varscan2
- PCDHA11 | c.71G>T p.W24L | Missense Mutation (SNP) | VAF 72/198 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.806); catalogued as COSV56482856; called by muse, mutect2, varscan2
- PCDHAC1 | c.2178G>T p.R726S | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV53839751; called by muse, mutect2, varscan2
- PCDHB1 | c.1704C>G p.N568K | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV60629843, COSV60631383; called by muse, mutect2, varscan2
- PCDHB14 | c.909G>C p.L303F | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV53387013; called by muse, mutect2, varscan2
- PCDHB2 | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); catalogued as COSV52030137; called by muse, mutect2, varscan2
- PCDHB3 | c.2179G>T p.V727L | Missense Mutation (SNP) | VAF 83/282 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as COSV99165392; called by muse, mutect2, varscan2
- PCDHB4 | c.205G>T p.D69Y | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.664); catalogued as COSV52020161; called by muse, mutect2, varscan2
- PCDHB6 | c.2222G>T p.G741V | Missense Mutation (SNP) | VAF 100/311 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV50691043; called by muse, mutect2, varscan2
- PCDHB7 | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.491); catalogued as COSV50756320, COSV50760274; called by muse, mutect2, varscan2
- PCDHB8 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 82/253 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.703); catalogued as rs1554281646, COSV50756322; called by muse, mutect2, varscan2
- PCDHGB4 | c.1081G>A p.G361R | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV53911351; called by muse, mutect2, varscan2
- PCF11 | c.4304G>C p.G1435A | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.996); catalogued as COSV53528404; called by muse, mutect2, varscan2
- PDE4B | c.74G>T p.S25I | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.944); catalogued as COSV58468677; called by muse, mutect2, varscan2
- PDE8A | c.491G>T p.R164M | Missense Mutation (SNP) | VAF 110/375 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59635345; called by muse, mutect2, varscan2
- PDHA2 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.066); catalogued as COSV54777730; called by muse, mutect2, varscan2
- PEG3 | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55627888, COSV55629547; called by muse, mutect2, varscan2
- PEG3 | c.1531G>T p.G511* | Nonsense Mutation (SNP) | VAF 63/218 reads (29%) | catalogued as COSV55627901, COSV55628383; called by muse, mutect2, varscan2
- PFAS | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58978891; called by muse, mutect2, varscan2
- PGM2L1 | c.1479G>C p.L493F | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1385429403, COSV53345605; called by muse, mutect2, varscan2
- PHACTR3 | c.219G>T p.R73S | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749775255, COSV63025761; called by muse, mutect2, varscan2
- PI4KA | c.5024G>T p.W1675L | Missense Mutation (SNP) | VAF 58/137 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.155); catalogued as COSV55405980; called by muse, mutect2, varscan2
- PI4KA | c.3728G>T p.G1243V | Missense Mutation (SNP) | VAF 90/172 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55405997; called by muse, mutect2, varscan2
- PKD2 | c.1696G>T p.V566L | Missense Mutation (SNP) | VAF 54/108 reads (50%) | SIFT tolerated (0.41); PolyPhen benign (0.304); catalogued as rs1393860679, COSV52937038; called by muse, mutect2, varscan2
- PKHD1 | c.10215C>A p.C3405* | Nonsense Mutation (SNP) | VAF 26/76 reads (34%) | catalogued as COSV64383091; called by muse, mutect2, varscan2
- PLCH1 | c.2714C>A p.S905Y (on ENST00000340059 / NM_001130960.2; = p.S897Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.594); catalogued as COSV58189805; called by muse, mutect2, varscan2
- PLCH1 | c.421A>T p.R141W (on ENST00000340059 / NM_001130960.2; = p.R153W on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58189836; called by muse, mutect2, varscan2
- PLEKHH1 | c.1517G>T p.R506L | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV61281164; called by muse, mutect2, varscan2
- PLPPR4 | c.1732C>A p.Q578K | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64564723; called by muse, mutect2, varscan2
- PLXNA1 | c.2053G>A p.V685M | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.105); catalogued as rs767000075, COSV52523154; called by muse, mutect2, varscan2
- POF1B | c.1033C>T p.L345F | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53131388; called by muse, varscan2
- POU3F2 | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); catalogued as COSV60408558; called by muse, mutect2, varscan2
- POU4F1 | c.256A>G p.N86D | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as COSV65883894; called by muse, mutect2, varscan2
- PPARD | c.829G>C p.D277H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61098989; called by muse, mutect2, varscan2
- PPEF1 | c.1751-2A>T p.X584_splice | Splice Site (SNP) | VAF 39/58 reads (67%) | catalogued as COSV62995279; called by muse, mutect2, varscan2
- PPFIA1 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV54132402; called by muse, mutect2, varscan2
- PRDM1 | c.1372C>A p.H458N | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV100958829; called by muse, mutect2, varscan2
- PRKX | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 27/36 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780742984, COSV53322541; called by muse, mutect2, varscan2
- PRR23B | c.413A>T p.E138V | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV61493287; called by muse, mutect2, varscan2
- PRSS16 | c.161C>A p.A54E | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV57915012; called by muse, mutect2, varscan2
- PRSS36 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.874); catalogued as rs199725414, COSV51636107; called by muse, mutect2, varscan2
- PRSS36 | c.989G>T p.R330L | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.49); catalogued as COSV51636121; called by muse, mutect2, varscan2
- PRSS57 | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as COSV61385534; called by muse, mutect2, varscan2
- PSAT1 | c.239G>A p.C80Y | Missense Mutation (SNP) | VAF 20/290 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1488591230, COSV61302016; called by muse, mutect2
- PTPRC | c.2302T>A p.S768T | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.163); catalogued as COSV61407811; called by mutect2, varscan2
- PTPRG | c.2791A>G p.T931A | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV55631988; called by muse, mutect2, varscan2
- PYGL | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 18/157 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as COSV53584662; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 52/162 reads (32%) | catalogued as COSV99770138; called by muse, mutect2, varscan2
- RAG2 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57556705; called by muse, mutect2, varscan2
- RALGAPA1 | c.4646C>T p.P1549L | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV51878196; called by muse, mutect2, varscan2
- RASSF4 | c.133C>A p.R45S | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as COSV53573539; called by muse, mutect2, varscan2
- RBFOX2 | c.1108G>T p.G370C (on ENST00000438146 / NM_001349995.2; = p.G296W on NM_014309.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53263282; called by muse, mutect2
- RBM33 | c.1635G>T p.Q545H | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56629859; called by muse, mutect2, varscan2
- RCL1 | c.718G>T p.G240C | Missense Mutation (SNP) | VAF 187/240 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101099372, COSV67753923; called by muse, mutect2, varscan2
- RELN | c.9071C>T p.P3024L | Missense Mutation (SNP) | VAF 35/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV58989953; called by muse, mutect2, varscan2
- RELN | c.8311C>A p.Q2771K | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.766); catalogued as COSV58989961; called by muse, mutect2, varscan2
- RELN | c.4937-1G>T p.X1646_splice | Splice Site (SNP) | VAF 20/46 reads (43%) | catalogued as COSV58989975; called by muse, mutect2, varscan2
- RFX6 | c.1322C>T p.T441I | Missense Mutation (SNP) | VAF 54/150 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV60583851; called by muse, mutect2, varscan2
- RGS22 | c.1465C>A p.H489N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.158); catalogued as COSV62658429; called by muse, mutect2, varscan2
- RHOBTB1 | c.442G>T p.D148Y | Missense Mutation (SNP) | VAF 61/91 reads (67%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV61957940; called by muse, mutect2, varscan2
- RHPN1 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV56645208; called by muse, mutect2, varscan2
- RIOX1 | c.103A>T p.R35W | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); catalogued as COSV58373621; called by muse, mutect2, varscan2
- RP1L1 | c.5212C>T p.P1738S | Missense Mutation (SNP) | VAF 82/287 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as COSV66752713; called by muse, mutect2, varscan2
- RRM1 | c.1945G>T p.G649C | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV56163203; called by muse, mutect2, varscan2
- RTN1 | c.1694C>A p.A565E | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV50719589; called by mutect2, varscan2
- RXYLT1 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54167763; called by muse, mutect2, varscan2
- RYR1 | c.7772G>T p.R2591L | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.204); catalogued as rs758169018, COSV62091521; called by muse, mutect2, varscan2
- RYR2 | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 58/126 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV63669100; called by muse, mutect2, varscan2
- RYR3 | c.8602C>A p.Q2868K (on ENST00000389232; = p.Q2869K on NM_001036.6) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.542); catalogued as COSV66780801; called by muse, mutect2, varscan2
- SAP130 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 135/190 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV52095074; called by muse, mutect2, varscan2
- SCEL | c.802C>A p.Q268K (on ENST00000349847 / NM_144777.3; = p.Q248K on NM_003843.4) | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV62993053, COSV62994020; called by muse, mutect2, varscan2
- SDK1 | c.4465G>T p.E1489* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV67359445; called by muse, mutect2, varscan2
- SEC23B | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV52718903; called by muse, mutect2, varscan2
- SEC31A | c.1708G>A p.D570N (on ENST00000355196 / NM_001318120.1; = p.D531N on NM_016211.4) | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV52342272; called by muse, mutect2, varscan2
- SEL1L2 | c.2026G>T p.V676F | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.11); catalogued as COSV53148968, COSV99533758; called by muse, mutect2, varscan2
- SETD1A | c.3800G>A p.G1267E | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV52685670; called by muse, mutect2, varscan2
- SFMBT2 | c.215G>T p.S72I | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV62806450; called by muse, mutect2, varscan2
- SH2D3C | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.013); catalogued as COSV59119592; called by muse, mutect2, varscan2
- SHC4 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV60109681, COSV60110041; called by muse, mutect2, varscan2
- SHISA3 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 92/184 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as COSV59979571; called by muse, mutect2, varscan2
- SHISAL2A | c.526G>T p.E176* | Nonsense Mutation (SNP) | VAF 161/341 reads (47%) | catalogued as COSV68979445; called by muse, mutect2, varscan2
- SHPRH | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 40/104 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.113); catalogued as COSV51605754; called by muse, mutect2, varscan2
- SIGLEC1 | c.3691C>A p.P1231T | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as COSV52459914; called by muse, mutect2, varscan2
- SIGLEC10 | c.1757C>T p.P586L | Missense Mutation (SNP) | VAF 56/185 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as rs755021240, COSV59479653; called by muse, mutect2, varscan2
- SIPA1L2 | c.2593G>T p.G865C | Missense Mutation (SNP) | VAF 70/138 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.063); catalogued as COSV53385006; called by muse, mutect2, varscan2
- SIX1 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV55959360; called by muse, mutect2
- SLC12A1 | c.1940C>A p.P647Q | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66792606; called by muse, mutect2, varscan2
- SLC12A7 | c.961G>C p.D321H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV53755119; called by muse, mutect2, varscan2
- SLC1A2 | c.1016T>G p.V339G | Missense Mutation (SNP) | VAF 74/247 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53519378; called by muse, mutect2, varscan2
- SLC23A2 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 63/137 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57772031; called by muse, mutect2, varscan2
- SLC25A37 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51563407; called by muse, mutect2, varscan2
- SLC27A5 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as COSV54018368, COSV54019702; called by muse, mutect2, varscan2
- SLC35F4 | c.1081del p.E361Kfs*14 (on ENST00000339762 / NM_001352015.2; = p.E325Kfs*14 on NM_001206920.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as COSV100334128; called by mutect2, pindel, varscan2
- SLC4A4 | c.1825G>C p.D609H (on ENST00000264485 / NM_001098484.3; = p.D565H on NM_003759.4) | Missense Mutation (SNP) | VAF 69/141 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV52617219, COSV52629319; called by muse, mutect2, varscan2
- SLC6A16 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.193); catalogued as COSV60027245; called by muse, mutect2, varscan2
- SLC7A1 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV101060219, COSV66332075; called by muse, mutect2, varscan2
- SLC9C2 | c.2560A>G p.I854V | Missense Mutation (SNP) | VAF 75/148 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV62944346; called by muse, mutect2, varscan2
- SLF1 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs776454220, COSV54368104; called by muse, mutect2, varscan2
- SLITRK5 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 39/287 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV61521444, COSV61525376; called by muse, mutect2, varscan2
- SNAP47 | c.1248G>T p.Q416H | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59917193; called by muse, mutect2, varscan2
- SPHKAP | c.754G>C p.A252P | Missense Mutation (SNP) | VAF 235/353 reads (67%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.543); catalogued as COSV60871151; called by muse, mutect2, varscan2
- SPIRE2 | c.1516G>A p.G506S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.01); catalogued as COSV65554627; called by muse, mutect2, varscan2
- SPOCK3 | c.397G>T p.G133C | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV62719115; called by muse, mutect2, varscan2
- SPTLC3 | c.605T>C p.M202T | Missense Mutation (SNP) | VAF 12/239 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as COSV65464151; called by muse, mutect2
- SRPK2 | c.266G>T p.W89L | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100623712, COSV61959704; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2473G>A p.A825T | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.596); catalogued as COSV100561411; called by muse, mutect2, varscan2
- STYXL1 | c.169A>G p.N57D | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV50387999; called by muse, mutect2, varscan2
- SV2C | c.1513G>T p.V505F | Missense Mutation (SNP) | VAF 54/210 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV59215681; called by muse, mutect2, varscan2
- SVEP1 | c.9893G>C p.R3298T | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as COSV52836663; called by muse, mutect2, varscan2
- SWT1 | c.782A>T p.K261M | Missense Mutation (SNP) | VAF 119/227 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV62253362; called by muse, mutect2, varscan2
- SYCP2L | c.2269G>C p.E757Q | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.177); catalogued as COSV51651005; called by muse, mutect2, varscan2
- TAOK3 | c.836G>T p.R279L | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV66824972; called by muse, mutect2, varscan2
- TAS2R41 | c.877G>C p.V293L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV68765028; called by muse, mutect2, varscan2
- TATDN1 | c.202+1G>T p.X68_splice | Splice Site (SNP) | VAF 34/133 reads (26%) | catalogued as COSV52678191; called by muse, varscan2
- TATDN1 | c.154G>T p.G52* | Nonsense Mutation (SNP) | VAF 38/129 reads (29%) | catalogued as COSV52678198; called by muse, varscan2
- TBC1D15 | c.610C>G p.Q204E | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV59847936; called by muse, mutect2, varscan2
- TBC1D26 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs368471151, COSV68608823; called by muse, mutect2, varscan2
- TEKT1 | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV58622407, COSV58622706; called by muse, mutect2, varscan2
- TFB1M | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs779992470, COSV65698397; called by muse, mutect2, varscan2
- TGM4 | c.313G>T p.V105F | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV56093081; called by muse, varscan2
- THAP12 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52609745; called by muse, mutect2, varscan2
- THAP12 | c.367T>G p.S123A | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV52609753; called by muse, mutect2, varscan2
- TMC3 | c.2304del p.N768Kfs*17 | Frame Shift Del (DEL) | VAF 33/123 reads (27%) | catalogued as COSV100845914; called by mutect2, pindel, varscan2
- TMEM108 | c.1142C>T p.T381I | Missense Mutation (SNP) | VAF 63/176 reads (36%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV58865825; called by muse, mutect2, varscan2
- TMEM179 | c.275C>A p.T92K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.209); catalogued as COSV100482172, COSV58794746; called by muse, mutect2
- TMEM37 | c.330G>T p.M110I | Missense Mutation (SNP) | VAF 164/236 reads (69%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as COSV50027100; called by muse, mutect2, varscan2
- TMPRSS13 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV70625823; called by muse, mutect2, varscan2
- TMTC4 | c.631A>G p.I211V (on ENST00000376234 / NM_001350577.2; = p.I230V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as rs752661087, COSV60891577; called by muse, mutect2, varscan2
- TOP3A | c.2836G>C p.G946R | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV58175499; called by muse, mutect2, varscan2
- TRIM10 | c.1324G>T p.V442L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV64998333; called by muse, mutect2, varscan2
- TRIM26 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV68962952; called by muse, mutect2, varscan2
- TRIM42 | c.42G>A p.W14* | Nonsense Mutation (SNP) | VAF 151/371 reads (41%) | catalogued as COSV53880735; called by muse, mutect2, varscan2
- TRIML2 | c.1065C>G p.F355L | Missense Mutation (SNP) | VAF 98/212 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV58714950, COSV58716193; called by muse, varscan2
- TRPC1 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.702); catalogued as rs764030575, COSV56423357; called by muse, mutect2
- TRPC7 | c.1639G>T p.A547S | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV61454107; called by muse, mutect2, varscan2
- TRPM1 | c.4798G>A p.E1600K | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.159); catalogued as COSV56631494, COSV56641553; called by muse, mutect2, varscan2
- TTC17 | c.419G>T p.S140I | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV50006538, COSV50009036; called by muse, mutect2, varscan2
- TTC21B | c.3638A>T p.Y1213F | Missense Mutation (SNP) | VAF 73/108 reads (68%) | SIFT tolerated (0.61); PolyPhen benign (0.092); catalogued as COSV54628509; called by muse, mutect2, varscan2
- TTC27 | c.1339G>A p.A447T | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1203672940, COSV58649473; called by muse, mutect2, varscan2
- TTN | c.89383G>A p.G29795S (on ENST00000591111; = p.G22371S on NM_003319.4) | Missense Mutation (SNP) | VAF 172/264 reads (65%) | PolyPhen probably damaging (0.999); catalogued as COSV59923600; called by muse, mutect2, varscan2
- TTN | c.87925C>A p.Q29309K (on ENST00000591111; = p.Q21885K on NM_003319.4) | Missense Mutation (SNP) | VAF 73/108 reads (68%) | PolyPhen benign (0); catalogued as COSV59923634; called by muse, mutect2, varscan2
- TTN | c.76372G>A p.D25458N (on ENST00000591111; = p.D18034N on NM_003319.4) | Missense Mutation (SNP) | VAF 19/59 reads (32%) | PolyPhen benign (0.069); catalogued as COSV59923661; called by muse, mutect2, varscan2
- TTN | c.63663G>C p.W21221C (on ENST00000591111; = p.W13797C on NM_003319.4) | Missense Mutation (SNP) | VAF 49/82 reads (60%) | PolyPhen probably damaging (0.999); catalogued as COSV59923696; called by muse, mutect2, varscan2
- TTN | c.50235C>A p.D16745E (on ENST00000591111; = p.D9321E on NM_003319.4) | Missense Mutation (SNP) | VAF 77/110 reads (70%) | PolyPhen benign (0.168); catalogued as COSV59923728; called by muse, mutect2, varscan2
- TXNDC15 | c.871A>T p.I291F | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64379369; called by muse, mutect2, varscan2
- UNC13A | c.4747C>A p.R1583S | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53190182; called by muse, mutect2, varscan2
- URGCP | c.240G>T p.L80F (on ENST00000453200 / NM_001077663.3; = p.L71F on NM_017920.4) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV99787417; called by muse, mutect2, varscan2
- USP13 | c.1356C>G p.F452L | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV55863302; called by muse, varscan2
- UTRN | c.7447A>G p.I2483V | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs1319096853, COSV62329779; called by muse, mutect2, varscan2
- VIPR2 | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51103955; called by muse, mutect2, varscan2
- VPS13A | c.3902G>T p.W1301L | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV62438792; called by muse, mutect2
- VPS13A | c.3903G>T p.W1301C | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.758); catalogued as rs1421117318, COSV62426211; called by muse, mutect2
- VPS13B | c.10979C>G p.P3660R | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62135524; called by muse, mutect2, varscan2
- VPS18 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.339); catalogued as rs1254884497, COSV55029219, COSV55029450; called by muse, mutect2, varscan2
- VPS35 | c.2086G>T p.V696L | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV54477425; called by muse, mutect2, varscan2
- WDR70 | c.977G>T p.R326L | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54268389; called by muse, mutect2, varscan2
- WDR91 | c.681G>T p.L227F | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as COSV60368838; called by muse, mutect2, varscan2
- WIZ | c.4435G>T p.G1479C (on ENST00000673675 / NM_001371589.1; = p.G384C on NM_021241.3) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54605151; called by muse, mutect2, varscan2
- XIRP1 | c.228T>A p.D76E | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.51); catalogued as COSV61137340; called by muse, mutect2, varscan2
- XIRP2 | c.8906C>A p.S2969Y (on ENST00000628543; = p.S3144Y on NM_152381.6) | Missense Mutation (SNP) | VAF 112/172 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.246); catalogued as COSV54687094; called by muse, mutect2, varscan2
- YES1 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV58848526; called by muse, mutect2, varscan2
- ZEB2 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 82/159 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV57952690, COSV57968180; called by muse, mutect2, varscan2
- ZFR | c.2011A>G p.M671V | Missense Mutation (SNP) | VAF 44/126 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV54051075; called by muse, mutect2, varscan2
- ZNF257 | c.1019G>C p.G340A | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV71306361; called by muse, mutect2, varscan2
- ZNF304 | c.536G>C p.S179T | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.475); catalogued as COSV56583548; called by muse, mutect2, varscan2
- ZNF343 | c.892G>T p.V298L | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.158); catalogued as rs866471732, COSV53853012; called by muse, mutect2, varscan2
- ZNF493 | c.1292A>T p.H431L | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.074); catalogued as COSV62749367; called by muse, mutect2, varscan2
- ZNF560 | c.101A>T p.Q34L | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV56866319; called by muse, mutect2, varscan2
- ZNF626 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.332); catalogued as COSV74129071; called by muse, mutect2
- ZNF653 | c.1030G>T p.G344C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV53402252, COSV53402304; called by muse, mutect2, varscan2
- ZP2 | c.1889G>T p.C630F | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54812549; called by muse, mutect2, varscan2
- ADGRB1 | c.2122del p.D708Tfs*49 | Frame Shift Del (DEL) | VAF 4/26 reads (15%) | called by pindel, varscan2
- CACNB2 | c.286del p.R96Afs*65 (on ENST00000324631 / NM_201596.3; = p.R41Afs*65 on NM_000724.4) | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- CSRNP3 | c.567dup p.G190Wfs*6 | Frame Shift Ins (INS) | VAF 160/248 reads (65%) | called by mutect2, varscan2
- DYTN | c.1040dup p.E348Gfs*8 | Frame Shift Ins (INS) | VAF 73/106 reads (69%) | called by mutect2, varscan2
- FRG2C | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | called by muse, mutect2, varscan2
- HSDL2 | c.714del p.F238Lfs*12 | Frame Shift Del (DEL) | VAF 70/145 reads (48%) | called by mutect2, pindel, varscan2
- IGHV1OR21-1 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.658); called by muse, mutect2
- IGKV1-39 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.11); called by mutect2, varscan2
- LAMA2 | c.1841_1842del p.E614Gfs*16 | Frame Shift Del (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- MAGEB4 | c.889_890delinsA p.P297Tfs*12 | Frame Shift Del (DEL) | VAF 36/67 reads (54%) | called by pindel, varscan2*
- MOS | c.745del p.E249Sfs*3 | Frame Shift Del (DEL) | VAF 37/115 reads (32%) | called by mutect2, pindel, varscan2
- MROH2B | c.2473del p.H825Tfs*21 | Frame Shift Del (DEL) | VAF 9/43 reads (21%) | called by mutect2, pindel, varscan2
- MTMR9 | c.1636del p.Q546Rfs*38 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- NOBOX | c.569del p.G190Efs*3 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- OR9G1 | c.641dup p.A215Gfs*50 | Frame Shift Ins (INS) | VAF 55/374 reads (15%) | called by mutect2, pindel, varscan2
- PCDHA13 | c.1856_1857del p.R619Hfs*37 | Frame Shift Del (DEL) | VAF 30/148 reads (20%) | called by pindel, varscan2
- PCDHB13 | c.1793A>T p.Q598L | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- POTEA | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PRAG1 | c.4022del p.G1341Afs*17 | Frame Shift Del (DEL) | VAF 67/216 reads (31%) | called by mutect2, pindel, varscan2
- RGS22 | c.435dup p.L146Ifs*37 | Frame Shift Ins (INS) | VAF 31/110 reads (28%) | called by mutect2, pindel, varscan2
- SMCHD1 | c.4435-2_4440del p.X1479_splice | Splice Site (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- SPN | c.540dup p.G181Rfs*12 | Frame Shift Ins (INS) | VAF 90/340 reads (26%) | called by mutect2, pindel, varscan2
- SPPL2B | c.1270del p.V424Cfs*36 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- SRCIN1 | c.2197G>T p.E733* (on ENST00000621492; = p.E699* on NM_025248.3) | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | called by muse, mutect2, varscan2
- TJP1 | c.4676del p.H1559Lfs*17 | Frame Shift Del (DEL) | VAF 93/348 reads (27%) | called by mutect2, pindel, varscan2
- TRAV22 | c.308G>T p.G103V | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TRAV3 | c.314C>A p.S105Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TRAV38-2DV8 | c.151G>C p.D51H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TRAV8-1 | c.159C>G p.F53L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- TRAV8-4 | c.250G>C p.A84P | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- TRGV8 | c.141T>G p.N47K | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZNF468 | c.186del p.Q63Kfs*6 | Frame Shift Del (DEL) | VAF 46/199 reads (23%) | called by mutect2, pindel, varscan2
- ACACB | c.2970G>A p.E990= | Silent (SNP) | VAF 19/280 reads (7%) | catalogued as rs1278040143, COSV58129896; called by muse, mutect2
- ADAMTS19 | c.831T>A p.R277= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV50734438; called by muse, mutect2
- ADAMTS20 | c.1659T>C p.R553= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs1374386661, COSV67128528; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.492C>G p.S164= | Silent (SNP) | VAF 49/153 reads (32%) | catalogued as COSV58441493, COSV58442037, COSV58442617; called by muse, mutect2, varscan2
- AFF3 | c.3426G>T p.L1142= | Silent (SNP) | VAF 74/115 reads (64%) | catalogued as rs1433045501, COSV57843949; called by muse, mutect2, varscan2
- AHNAK | c.8256A>T p.A2752= | Silent (SNP) | VAF 127/338 reads (38%) | catalogued as COSV57205986; called by muse, mutect2, varscan2
- ALDH7A1 | c.999G>A p.A333= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as rs563675719, COSV69259076; called by muse, mutect2, varscan2
- ALLC | c.444C>A p.S148= | Silent (SNP) | VAF 107/222 reads (48%) | catalogued as COSV52993332; called by muse, mutect2, varscan2
- ANKEF1 | c.1692T>C p.F564= | Silent (SNP) | VAF 23/143 reads (16%) | catalogued as COSV65692042; called by muse, mutect2, varscan2
- ANKRD20A1 | c.948A>G p.K316= | Silent (SNP) | VAF 138/442 reads (31%) | called by muse, varscan2
- APOB | c.1063C>T p.L355= | Silent (SNP) | VAF 69/138 reads (50%) | catalogued as COSV51926627, COSV99263540; called by muse, mutect2, varscan2
- ATN1 | c.1680A>G p.Q560= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as COSV63110402; called by muse, mutect2, varscan2
- ATP8B4 | c.852G>T p.L284= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV52710767; called by muse, mutect2, varscan2
- BRD1 | c.1947T>C p.Y649= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV53455328; called by muse, mutect2, varscan2
- BRD8 | c.498A>G p.A166= | Silent (SNP) | VAF 67/170 reads (39%) | catalogued as COSV50145736; called by muse, mutect2, varscan2
- C1orf216 | c.87A>T p.P29= | Silent (SNP) | VAF 45/82 reads (55%) | catalogued as COSV52047692; called by muse, mutect2, varscan2
- C1orf226 | c.54C>T p.S18= | Silent (SNP) | VAF 20/88 reads (23%) | catalogued as COSV63394648; called by muse, mutect2, varscan2
- CABIN1 | c.3744C>A p.I1248= | Silent (SNP) | VAF 64/159 reads (40%) | catalogued as COSV54078851; called by muse, mutect2, varscan2
- CCL24 | c.135C>T p.N45= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV56116082; called by muse, mutect2, varscan2
- CCT6A | c.981T>A p.A327= | Silent (SNP) | VAF 39/114 reads (34%) | catalogued as COSV51904716; called by muse, mutect2, varscan2
- CD209 | c.384C>G p.T128= | Silent (SNP) | VAF 83/264 reads (31%) | catalogued as COSV52650671, COSV52650783; called by muse, varscan2
- CD34 | c.18C>T p.G6= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as rs1409897819, COSV60412016; called by muse, mutect2, varscan2
- CD5 | c.579C>A p.T193= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as COSV61717949; called by muse, mutect2, varscan2
- CDH10 | c.153T>C p.R51= | Silent (SNP) | VAF 65/218 reads (30%) | catalogued as COSV52573143; called by muse, mutect2, varscan2
- CEP126 | c.2724C>T p.T908= | Silent (SNP) | VAF 78/235 reads (33%) | catalogued as COSV54822517; called by muse, mutect2, varscan2
- COL2A1 | c.1872T>A p.G624= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as COSV61528585; called by muse, mutect2, varscan2
- COQ10B | c.396G>T p.V132= | Silent (SNP) | VAF 113/165 reads (68%) | catalogued as COSV55836005; called by muse, mutect2, varscan2
- CPZ | c.1293T>C p.N431= (on ENST00000360986 / NM_001014447.3; = p.N420= on NM_003652.3) | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs573953659, COSV59921909; called by muse, mutect2, varscan2
- CXCR1 | c.768G>T p.L256= | Silent (SNP) | VAF 12/228 reads (5%) | catalogued as COSV55281283; called by muse, mutect2
- DAPP1 | c.612A>G p.P204= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs577479651, COSV56450201; called by muse, mutect2, varscan2
- DCSTAMP | c.684C>A p.G228= | Silent (SNP) | VAF 59/163 reads (36%) | catalogued as COSV52576649; called by muse, mutect2, varscan2
- DDAH2 | c.801G>A p.K267= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as COSV65383686; called by muse, mutect2, varscan2
- DDX39B | c.1167A>T p.T389= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV66018723; called by muse, mutect2, varscan2
- DENND4C | c.1546C>T p.L516= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV66821615; called by muse, mutect2, varscan2
- DLD | c.573T>A p.P191= | Silent (SNP) | VAF 35/166 reads (21%) | catalogued as COSV52737124; called by muse, mutect2, varscan2
- DRD3 | c.36C>T p.N12= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV55679101; called by muse, mutect2, varscan2
- DUOXA2 | c.561G>A p.A187= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV50993172; called by muse, mutect2, varscan2
- EIF4G2 | c.186C>T p.S62= | Silent (SNP) | VAF 110/353 reads (31%) | catalogued as rs376340882, COSV60596192; called by muse, mutect2, varscan2
- ENPP2 | c.1776A>G p.T592= (on ENST00000075322 / NM_001040092.3; = p.T644= on NM_006209.5) | Silent (SNP) | VAF 191/645 reads (30%) | catalogued as COSV50010628; called by muse, mutect2, varscan2
- ETV1 | c.615G>A p.R205= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV54138436; called by muse, mutect2, varscan2
- FAM118A | c.942T>A p.A314= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV53416340; called by muse, mutect2, varscan2
- FBXO32 | c.111C>T p.L37= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as COSV71551924; called by muse, mutect2, varscan2
- FBXW7 | c.1959G>C p.T653= (on ENST00000281708 / NM_001349798.2; = p.T573= on NM_018315.5) | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as COSV55899122, COSV55917020; called by muse, mutect2, varscan2
- FLNC | c.6616C>A p.R2206= | Silent (SNP) | VAF 39/70 reads (56%) | catalogued as rs867032077, COSV57951945; called by muse, mutect2, varscan2
- FNDC8 | c.627C>T p.F209= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as COSV50100705; called by muse, mutect2, varscan2
- FSTL5 | c.1725C>A p.T575= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV60184299; called by muse, mutect2, varscan2
- GATA4 | c.858G>A p.A286= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs757208344, COSV58732632; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNA13 | c.951C>T p.H317= | Silent (SNP) | VAF 46/115 reads (40%) | catalogued as COSV71474466, COSV71475194; called by muse, mutect2, varscan2
- GRM3 | c.525C>T p.S175= | Silent (SNP) | VAF 79/236 reads (33%) | catalogued as COSV64468430, COSV64470873; called by muse, mutect2, varscan2
- H4C13 | c.72C>T p.R24= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as COSV60693163; called by muse, mutect2, varscan2
- HAVCR1 | c.420C>G p.T140= | Silent (SNP) | VAF 116/404 reads (29%) | catalogued as COSV100208459, COSV59398378, COSV59400159; called by muse, varscan2
- HSPG2 | c.1218C>T p.P406= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV65930056; called by muse, mutect2, varscan2
- IGF2BP3 | c.567C>A p.S189= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as COSV51681182; called by mutect2, varscan2
- KDM2B | c.945C>T p.A315= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as rs369372892; called by muse, mutect2, varscan2
- KLHL1 | c.999C>A p.A333= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV64768146; called by muse, mutect2, varscan2
- KRTAP10-12 | c.309C>A p.A103= | Silent (SNP) | VAF 118/311 reads (38%) | catalogued as COSV59954439; called by muse, varscan2
- KXD1 | c.363G>T p.T121= | Silent (SNP) | VAF 177/601 reads (29%) | catalogued as COSV55889104; called by muse, varscan2
- LCMT2 | c.1503A>T p.R501= | Silent (SNP) | VAF 110/264 reads (42%) | catalogued as COSV59789709; called by muse, varscan2
- LOXL3 | c.2106A>T p.A702= | Silent (SNP) | VAF 31/166 reads (19%) | catalogued as COSV51206359; called by muse, mutect2, varscan2
- LPA | c.3030G>A p.E1010= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV60298295; called by muse, mutect2, varscan2
- LRP1B | c.687A>T p.S229= | Silent (SNP) | VAF 38/75 reads (51%) | catalogued as COSV67195182; called by muse, mutect2, varscan2
- LRRIQ3 | c.1251C>A p.L417= | Silent (SNP) | VAF 48/98 reads (49%) | catalogued as COSV63041778; called by muse, mutect2, varscan2
- LRRIQ4 | c.711G>C p.S237= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as COSV61618794, COSV61620471; called by muse, mutect2, varscan2
- MAN2B1 | c.1263G>C p.L421= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as COSV55470556; called by muse, mutect2, varscan2
- MAP1LC3C | c.201C>A p.T67= | Silent (SNP) | VAF 94/176 reads (53%) | catalogued as COSV61803538, COSV61803745; called by muse, varscan2
- MELK | c.1258T>C p.L420= | Silent (SNP) | VAF 33/136 reads (24%) | catalogued as COSV53197456; called by muse, mutect2, varscan2
- MRPL19 | c.186C>T p.I62= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as rs1295543900, COSV62566660; called by muse, varscan2
- MUC16 | c.39810A>G p.G13270= | Silent (SNP) | VAF 89/231 reads (39%) | catalogued as rs1235511563, COSV66690335; called by muse, mutect2, varscan2
- MUC17 | c.2640T>G p.S880= | Silent (SNP) | VAF 196/481 reads (41%) | catalogued as COSV60282213; called by muse, mutect2, varscan2
- MYO15A | c.4506A>C p.S1502= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV52753151; called by muse, mutect2, varscan2
- MYO7B | c.384C>T p.G128= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as rs370063306; called by muse, mutect2, varscan2
- NFATC2IP | c.1053G>T p.R351= | Silent (SNP) | VAF 25/138 reads (18%) | catalogued as COSV57909855; called by muse, mutect2, varscan2
- NLGN4X | c.2247C>T p.H749= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs777673585, COSV52008090; called by muse, mutect2, varscan2
- NOD2 | c.1119T>A p.R373= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV56048801; called by mutect2, varscan2
- NTNG2 | c.1122C>T p.V374= | Silent (SNP) | VAF 109/170 reads (64%) | catalogued as COSV62365103; called by muse, mutect2, varscan2
- OR4A47 | c.426G>C p.L142= | Silent (SNP) | VAF 64/164 reads (39%) | catalogued as COSV71444863; called by muse, mutect2, varscan2
- OR51G2 | c.666T>A p.S222= | Silent (SNP) | VAF 24/94 reads (26%) | catalogued as COSV58992038; called by muse, mutect2, varscan2
- OR56A3 | c.801G>T p.V267= | Silent (SNP) | VAF 77/285 reads (27%) | catalogued as COSV61568614; called by muse, varscan2
- OR5B2 | c.765C>T p.F255= | Silent (SNP) | VAF 23/95 reads (24%) | catalogued as COSV56907726, COSV56908428; called by muse, mutect2, varscan2
- OR6F1 | c.168T>C p.H56= | Silent (SNP) | VAF 111/217 reads (51%) | catalogued as rs1306310942, COSV57467126; called by muse, mutect2, varscan2
- OR7G2 | c.234C>A p.T78= | Silent (SNP) | VAF 46/137 reads (34%) | catalogued as rs749097041, COSV59687449; called by muse, mutect2, varscan2
- OR9G4 | c.729C>A p.S243= | Silent (SNP) | VAF 45/142 reads (32%) | catalogued as COSV57247928; called by muse, mutect2, varscan2
- OR9I1 | c.549C>A p.P183= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs138832584, COSV56925755; called by muse, mutect2, varscan2
- P2RX1 | c.519C>A p.I173= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as COSV56653160; called by muse, mutect2, varscan2
- PABPC4 | c.1419G>C p.P473= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1190574667, COSV63293288; called by muse, varscan2
- PCDH19 | c.1923C>T p.I641= | Silent (SNP) | VAF 23/37 reads (62%) | catalogued as COSV55258416; called by muse, mutect2, varscan2
- PCDHA6 | c.30A>T p.G10= | Silent (SNP) | VAF 73/229 reads (32%) | catalogued as COSV65350171; called by muse, mutect2, varscan2
- PCDHB16 | c.1536C>T p.H512= | Silent (SNP) | VAF 29/110 reads (26%) | catalogued as rs782049051, COSV53358966; called by muse, mutect2, varscan2
- PCDHB9 | c.1968C>A p.A656= | Silent (SNP) | VAF 43/188 reads (23%) | catalogued as COSV53376213; called by muse, mutect2, varscan2
- PEAK1 | c.3327C>T p.N1109= | Silent (SNP) | VAF 53/150 reads (35%) | catalogued as COSV56932002; called by muse, mutect2, varscan2
- PGLYRP1 | c.154C>T p.L52= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as rs1163526473, COSV50516506; called by muse, mutect2, varscan2
- PHKB | c.948A>G p.T316= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as COSV54516310; called by muse, mutect2, varscan2
- PITPNM3 | c.1479G>T p.R493= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV52593471; called by muse, mutect2
- PJVK | c.732G>C p.L244= | Silent (SNP) | VAF 58/86 reads (67%) | catalogued as COSV64306277; called by muse, mutect2, varscan2
- PKLR | c.453G>T p.V151= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV61360614; called by muse, mutect2, varscan2
- PLEKHF1 | c.114C>T p.G38= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as rs757300561, COSV71409976; called by muse, mutect2, varscan2
- PNCK | c.594G>T p.L198= (on ENST00000340888 / NM_001366975.1; = p.L281= on NM_001039582.3) | Silent (SNP) | VAF 39/49 reads (80%) | catalogued as COSV61742838; called by muse, mutect2, varscan2
- PRAM1 | c.1440G>T p.R480= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV55312419; called by muse, mutect2, varscan2
- PRKAR2B | c.618T>C p.D206= | Silent (SNP) | VAF 26/130 reads (20%) | catalogued as COSV55923037; called by muse, mutect2, varscan2
- PRKCG | c.1002C>A p.P334= | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV54724928; called by muse, mutect2, varscan2
- RAD50 | c.462C>T p.V154= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as rs1554097772, COSV54748729; ClinVar: likely benign; called by muse, mutect2, varscan2
- RBM7 | c.6G>T p.G2= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as COSV57784070; called by muse, mutect2
- RECK | c.840T>C p.P280= | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as rs1017070308, COSV65034841; called by muse, mutect2, varscan2
- ROBO3 | c.3354T>C p.P1118= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV67299679; called by muse, mutect2, varscan2
- RYR3 | c.10092C>T p.S3364= (on ENST00000389232; = p.S3365= on NM_001036.6) | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV101213571, COSV66780807; called by muse, mutect2, varscan2
- SBSN | c.1494C>A p.V498= (on ENST00000452271 / NM_001166034.2; = p.V155= on NM_198538.4) | Silent (SNP) | VAF 35/112 reads (31%) | catalogued as COSV71733073; called by muse, mutect2, varscan2
- SCN3A | c.2013C>A p.P671= | Silent (SNP) | VAF 49/86 reads (57%) | catalogued as COSV51803587; called by muse, mutect2, varscan2
- SCN3B | c.132C>T p.R44= | Silent (SNP) | VAF 82/205 reads (40%) | catalogued as COSV54798434; called by muse, mutect2, varscan2
- SEC16B | c.546G>A p.R182= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs1377677867, COSV57624079; called by muse, mutect2, varscan2
- SERPINA7 | c.648A>G p.P216= | Silent (SNP) | VAF 65/110 reads (59%) | catalogued as COSV59665059; called by muse, mutect2, varscan2
- SERPINB4 | c.1167C>A p.S389= | Silent (SNP) | VAF 71/143 reads (50%) | catalogued as COSV61984390; called by muse, mutect2, varscan2
- SIGLEC6 | c.87G>C p.R29= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV58432460; called by muse, mutect2, varscan2
- SLAIN1 | c.1353A>T p.P451= (on ENST00000466548; = p.P188= on NM_144595.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 69/154 reads (45%) | catalogued as COSV57385588; called by muse, mutect2, varscan2
- SLAMF1 | c.189C>A p.V63= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV52498021; called by muse, mutect2, varscan2
- SLC35F4 | c.837C>A p.S279= (on ENST00000339762 / NM_001352015.2; = p.S243= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV100333911; called by mutect2, varscan2
- SLC3A2 | c.1407G>A p.G469= | Silent (SNP) | VAF 160/585 reads (27%) | catalogued as rs777869567, COSV58602966; called by muse, varscan2
- SLC6A13 | c.1809G>A p.*603= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV58255778; called by muse, mutect2, varscan2
- SLC7A13 | c.318G>T p.G106= | Silent (SNP) | VAF 19/68 reads (28%) | catalogued as COSV52532281; called by muse, mutect2, varscan2
- SLC9A9 | c.828G>T p.G276= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as COSV57220719; called by muse, mutect2, varscan2
- SLIT2 | c.3348C>G p.P1116= | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as COSV56563644; called by muse, mutect2, varscan2
- SPATA25 | c.534C>A p.I178= | Silent (SNP) | VAF 47/96 reads (49%) | catalogued as COSV51940944; called by muse, mutect2, varscan2
- STAB2 | c.2883C>A p.T961= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as COSV101185667, COSV66335582, COSV66345583; called by muse, mutect2, varscan2
- STRADB | c.234G>A p.R78= | Silent (SNP) | VAF 138/215 reads (64%) | catalogued as COSV52042897; called by muse, mutect2, varscan2
- TCF23 | c.252G>T p.R84= | Silent (SNP) | VAF 43/109 reads (39%) | catalogued as COSV56078035, COSV56079249; called by muse, mutect2, varscan2
- THOP1 | c.1494G>T p.R498= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV57017960; called by muse, mutect2, varscan2
- TLR4 | c.837C>A p.G279= (on ENST00000355622 / NM_138554.5; = p.G239= on NM_003266.4) | Silent (SNP) | VAF 167/239 reads (70%) | catalogued as COSV62922629, COSV62923560; called by muse, mutect2, varscan2
- TMEM213 | c.210C>T p.Y70= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs376442871; called by muse, mutect2, varscan2
- TNR | c.2163C>A p.T721= | Silent (SNP) | VAF 31/186 reads (17%) | catalogued as COSV54874533; called by muse, mutect2, varscan2
- TRDN | c.1527T>A p.P509= | Silent (SNP) | VAF 42/80 reads (53%) | catalogued as COSV62115284; called by muse, mutect2, varscan2
- TRIB2 | c.516G>T p.V172= | Silent (SNP) | VAF 64/148 reads (43%) | catalogued as COSV50224105; called by muse, mutect2, varscan2
- TRIM24 | c.1989A>G p.S663= (on ENST00000343526 / NM_015905.3; = p.S629= on NM_003852.4) | Silent (SNP) | VAF 52/191 reads (27%) | catalogued as COSV58969959; called by muse, mutect2, varscan2
- TRPC7 | c.939C>A p.L313= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs774067254, COSV61454123, COSV61458366; called by muse, mutect2, varscan2
- TSPAN33 | c.264C>A p.R88= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV56825672; called by muse, mutect2, varscan2
- TWF2 | c.912G>T p.T304= | Silent (SNP) | VAF 67/133 reads (50%) | catalogued as COSV59725902; called by muse, mutect2, varscan2
- UACA | c.618A>T p.L206= | Silent (SNP) | VAF 81/239 reads (34%) | catalogued as COSV59853914; called by muse, mutect2, varscan2
- UBE3A | c.1203C>T p.I401= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV51661983; called by muse, mutect2, varscan2
- VIM | c.819T>A p.R273= | Silent (SNP) | VAF 35/48 reads (73%) | catalogued as COSV56404939; called by muse, mutect2, varscan2
- VPS13B | c.8730C>A p.P2910= | Silent (SNP) | VAF 42/190 reads (22%) | catalogued as COSV100662251, COSV62140232; called by muse, mutect2, varscan2
- WAS | c.126A>G p.K42= | Silent (SNP) | VAF 50/80 reads (63%) | catalogued as COSV64996700; called by muse, mutect2, varscan2
- WDR7 | c.1827T>C p.A609= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as COSV54349354, COSV99589898; called by muse, mutect2, varscan2
- WFIKKN2 | c.888G>A p.L296= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV60958083; called by muse, mutect2, varscan2
- ZC4H2 | c.645C>A p.P215= | Silent (SNP) | VAF 21/31 reads (68%) | catalogued as COSV62002409; called by muse, mutect2, varscan2
- ZIK1 | c.196C>T p.L66= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as COSV56736372, COSV56736597; called by muse, mutect2, varscan2
- ZNF208 | c.3135T>G p.T1045= | Silent (SNP) | VAF 50/186 reads (27%) | catalogued as COSV68101858, COSV68103080; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840334 C>T | 5'Flank (SNP) | VAF 66/138 reads (48%) | catalogued as COSV58329574; called by muse, mutect2, varscan2
- BIN1 | c.858-1470G>A | Intron (SNP) | VAF 72/108 reads (67%) | catalogued as rs1225779513, COSV99388110; called by muse, mutect2, varscan2
- CR2 | c.*2C>G | 3'UTR (SNP) | VAF 56/93 reads (60%) | catalogued as COSV100889656; called by muse, mutect2, varscan2
- DLG2 | c.205-65706C>A | Intron (SNP) | VAF 80/257 reads (31%) | catalogued as COSV99716612; called by muse, mutect2, varscan2
- DST | c.4296+4544A>T | Intron (SNP) | VAF 47/188 reads (25%) | catalogued as COSV99757052; called by muse, mutect2, varscan2
- FAIM | c.-22-1654C>A | Intron (SNP) | VAF 62/147 reads (42%) | catalogued as COSV100623920; called by muse, mutect2, varscan2
- MIR514A1 | n.21C>T | RNA (SNP) | VAF 13/19 reads (68%) | catalogued as rs782379159; called by muse, mutect2, varscan2
- MIR655 | n.21G>A | RNA (SNP) | VAF 46/129 reads (36%) | called by muse, mutect2, varscan2
- NBPF11 | c.-548-3026G>T | Intron (SNP) | VAF 169/312 reads (54%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31079G>T | Intron (SNP) | VAF 71/216 reads (33%) | catalogued as COSV99828550; called by muse, mutect2, varscan2
- PKD1L2 | chr16:81165882 G>A | 3'Flank (SNP) | VAF 13/27 reads (48%) | called by muse, mutect2, varscan2
- RBPMS | c.528+4919C>A | Intron (SNP) | VAF 48/181 reads (27%) | catalogued as rs143076913, COSV99824056; called by muse, mutect2, varscan2
- RN7SL106P | chr15:23163846 G>T | 5'Flank (SNP) | VAF 42/186 reads (23%) | called by muse, mutect2, varscan2
- SNORD115-43 | n.20T>C | RNA (SNP) | VAF 44/373 reads (12%) | called by muse, mutect2, varscan2
- SNORD116-5 | n.16C>A | RNA (SNP) | VAF 53/153 reads (35%) | called by muse, mutect2, varscan2
- TRIM14 | c.*130C>T | 3'UTR (SNP) | VAF 36/285 reads (13%) | catalogued as COSV52963318, COSV99271594; called by muse, mutect2, varscan2
- UBTFL2 | n.85C>A | RNA (SNP) | VAF 83/292 reads (28%) | catalogued as rs756699834; called by muse, mutect2, varscan2
- UNC5D | c.104-4825A>T | Intron (SNP) | VAF 30/87 reads (34%) | catalogued as COSV99775952; called by muse, mutect2, varscan2
- USH1C | c.1285-7470C>A | Intron (SNP) | VAF 49/158 reads (31%) | catalogued as COSV99140264; called by muse, mutect2, varscan2
- WT1 | chr11:32439116 C>G | 5'Flank (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- ZNF665 | c.-53-9139G>T | Intron (SNP) | VAF 46/165 reads (28%) | catalogued as COSV67213903; called by muse, mutect2, varscan2
- ZSCAN32 | c.839-757C>G | Intron (SNP) | VAF 101/314 reads (32%) | catalogued as COSV59234361; called by muse, mutect2, varscan2
